Somatic mutation profile of tumor specimen TCGA-HW-7489-01A (aliquot TCGA-HW-7489-01A-11D-2024-08) from TCGA case TCGA-HW-7489, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.9 years (14,201 days).
Specimen TCGA-HW-7489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02fda2ab-82b5-41c9-9512-c33e1e0930a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7489-10A (Blood Derived Normal), aliquot TCGA-HW-7489-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeea33e2-cdbb-4888-b924-7f312564a449

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANO6 | c.1783-1G>T p.X595_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as COSV57656289; called by muse, mutect2
- C3 | c.1845+2T>C p.X615_splice | Splice Site (SNP) | VAF 28/242 reads (12%) | catalogued as COSV55568162, COSV55576867, COSV99835816; called by muse, mutect2, varscan2
- CDH16 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as rs1320272533, COSV55334640; called by muse, mutect2, varscan2
- CPPED1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs775083202, COSV55495457; called by muse, mutect2, varscan2
- CR1L | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | catalogued as COSV54322326; called by muse, mutect2
- FADS2 | c.972C>G p.N324K | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV53896565, COSV53902112; called by muse, mutect2
- FAT3 | c.11995C>T p.Q3999* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV53072761, COSV53103429; called by muse, mutect2, varscan2
- KDM3B | c.269T>A p.L90H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV58687544; called by muse, mutect2, varscan2
- MCM10 | c.1417A>G p.I473V (on ENST00000484800 / NM_182751.3; = p.I472V on NM_018518.5) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752996916, COSV66332986; called by muse, mutect2, varscan2
- MECOM | c.686C>T p.T229M (on ENST00000468789 / NM_001105078.4; = p.T417M on NM_004991.4) | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1260144549, COSV52958933, COSV52961988, COSV52975844; called by muse, mutect2, varscan2
- TCF7L2 | c.1226T>G p.L409R (on ENST00000355995 / NM_001367943.1; = p.L386R on NM_030756.5) | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53336017; called by muse, mutect2
- TRIM13 | c.-6-1G>A | Splice Site (SNP) | VAF 29/103 reads (28%) | catalogued as COSV53947845; called by muse, mutect2, varscan2
- ATRX | c.2093dup p.D699Gfs*2 | Frame Shift Ins (INS) | VAF 70/140 reads (50%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2742C>T p.D914= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs760730607, COSV65887774; called by muse, mutect2, varscan2
- FAM193A | c.2367C>T p.C789= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs760640106, COSV61190643; called by mutect2, varscan2
- FRMPD4 | c.1686C>T p.G562= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs377028350, COSV66211040; called by muse, mutect2, varscan2
- GRK6 | c.57C>T p.G19= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs373947875; called by muse, mutect2, varscan2
- SIM2 | c.651G>A p.L217= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs768360099, COSV51765794; called by muse, mutect2, varscan2
- SLCO1B1 | c.2046T>C p.S682= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV104376776, COSV57006727; called by muse, mutect2, varscan2
